Somatic mutation profile of tumor specimen TARGET-15-SJMPAL042789-09A.2 (aliquot TARGET-15-SJMPAL042789-09A.2-01D) from TARGET case TARGET-15-SJMPAL042789, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,371 days).
Specimen TARGET-15-SJMPAL042789-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 104a500f-b693-4c82-8741-530b7f485afb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL042789-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL042789-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7096188-4a48-4f4b-9962-4768c6afd103

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 2, Silent 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTAGE6 | c.709G>C p.E237Q | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs747558071; called by muse, mutect2
- GREB1 | c.2473C>A p.Q825K | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.543); catalogued as COSV52183427; called by muse, mutect2
- SLC9A1 | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV99849850; called by muse, mutect2
- EZH1 | c.1075G>T p.G359C | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2
- GNL1 | c.1614G>T p.E538D | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.288); called by muse, mutect2
- GPR18 | c.44G>T p.S15I | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.009); called by muse, mutect2
- SEL1L2 | c.1968G>T p.W656C | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); called by muse, mutect2
- SVBP | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 6/62 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); called by muse, mutect2
- ACOT8 | c.240G>T p.L80= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- GALNT15 | c.333C>A p.G111= | Silent (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
- DHDDS | c.542+94C>A | Intron (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- PRAMEF1 | c.866+466C>A | Intron (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
